TCGA case TCGA-24-1551 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/499a9b57-ee1a-4012-bbab-c6ad955b5e0a

Demographics
Sex at birth: female; Race: white; Age at index: 53 years; Vital status: Dead; Days to death: 1,579 days (4.3 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 53.8 years (19,661 days); Year of diagnosis: 1997; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 10 days; Days to treatment end: 135 days; Number of cycles: 7; Treatment dose: 4,140 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 10 days; Days to treatment end: 135 days; Number of cycles: 7; Treatment dose: 2,080 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 790 days (2.2 years); Days to treatment end: 790 days (2.2 years); Number of cycles: 1; Treatment dose: 13 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 842 days (2.3 years); Days to treatment end: 975 days (2.7 years); Number of cycles: 6; Treatment dose: 3,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,227 days (3.4 years); Days to treatment end: 1,254 days (3.4 years); Number of cycles: 2; Treatment dose: 160 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,289 days (3.5 years); Days to treatment end: 1,437 days (3.9 years); Number of cycles: 19; Treatment dose: 3,020 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,549 days (4.2 years); Days to treatment end: 1,549 days (4.2 years); Number of cycles: 1; Treatment dose: 80 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 55.9 years (20,425 days); Days to diagnosis: 764 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 764 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 764 days (2.1 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,579 days (4.3 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Other.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1551-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-24-1551-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
  Slide TCGA-24-1551-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
- Sample TCGA-24-1551-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Taxol.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,579 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,579 days; disease-free interval: event (new tumor event after initially disease-free), 764 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 764 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-1551-01A-01D-0497-01): tumor purity 0.78, ploidy 2.13, whole-genome doublings 0.
